Surgical pathology report (de-identified scan), TCGA case TCGA-78-7537, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7537-01A (Primary Tumor).

HISTORY

Tissue taken at lobectomy.

MACROSCOPIC

Two specimens received.

1: The specimen is labelled "right upper lobe" and consists of a right upper lobectomy which measures 140 x 120 x 50 mm in maximum dimension. On palpation there is a firm to hard mass located in the apical segment, predominantly on the posteromedial aspect. The mass measures approximately 60 x 65 x 40 mm in maximum dimension. There is puckering of the overlying pleural surface at the apex. The pleural surface on the medial aspect of the specimen has a fibrinous-type exudate. On sectioning there is a solid lobulated tumour which has a yellow greyish-white cut surface. It, in places, has a villous-like architecture. There is haemorrhage scattered throughout the tumour. The tumour appears to abut the pleural surface. The tumour appears to lie at least 20 mm from the bronchial resection margin. There is a soft tissue resection margin which has a row of staples and measures 85 mm in length. The tumour is well clear of this. The surrounding adjacent uninvolved lung parenchyma has a collapsed appearance. [1A, bronchial resection margin; 1B-F, tumour; 1G, adjacent uninvolved lung parenchyma; 1H, hilar lymph nodes].

2: The specimen is labelled "hilar lymph node" and consists of four irregular greyish-black pieces of tissue which measure in aggregate 30 x 20 x 10 mm. [BIT, 2A].

MICROSCOPIC

1: Sections show a well differentiated adenocarcinoma. The tumour has a prominent bronchioloalveolar component with a marked papillary pattern. The cells are tall and columnar with variable cytoplasm ranging from non-mucinous to clear to mucinous. The lesion is subpleural but definite pleural invasion is not identified. There is no blood vessel invasion and no lymphatic permeation is seen. No perineural permeation is identified. The lesion is well clear of the bronchial resection margin. Tumour appears to be present at a diathermied margin, possibly related to pleura in block 1F. It is difficult to know whether this represents a true margin. No lymph node metastases are present. The adjacent lung shows evidence of emphysema. Within the random section of lung, there is a localised area of necrosis with surrounding fibrosis. Special stains for microorganisms will be performed.

2: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

SUMMARY

Right upper lobe lung and hilar lymph nodes:

- 1: Well differentiated adenocarcinoma; 65 mm in maximal dimension.
- 2: No blood vessel, lymphatic or perineural invasion present.
- 3: No pleural invasion identified; clear of bronchial margin but extends to an area of diathermy (see report).
- 4: No lymph node metastases.
- 5: T2N0MX
- 6: Emphysema and necrotic lesion; special stains for microorganisms being performed.
-

SUPPLEMENTARY REPORT

No micro-organisms are identified within the lung granuloma with special stains

Source: NCI Genomic Data Commons file 07bf0363-0eb1-4679-ab65-1b7a1ffbed6a (TCGA-78-7537.0BB9490C-1FB1-4D36-85A4-435565E9DB53.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).